Gene-level copy-number profile of specimen HCM-CSHL-0257-C18-85A from HCMI case HCM-CSHL-0257-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-CSHL-0257-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d90c8fd2-1531-4f5b-a777-e45599b5732a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0257-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/9bc2f747-cb5e-4083-b921-6cea419054e5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 6; copy number 2: 4,907; copy number 3: 2,282; copy number 4: 31,953; copy number 5: 4,086; copy number 6: 9,235; copy number 7: 1,367; copy number 8: 3,889; copy number 9: 1,156; copy number 11: 3; copy number 13: 14; copy number 17: 3; copy number 18: 3.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–7): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,179 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:72,031,804–75,724,589, 62 genes, copy number 9–18 (broad region; genes not listed).
- chr9:61,190,003–61,582,675, 8 genes, copy number 9: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr17:29,246,859–29,294,148, 2 genes, copy number 9: CRYBA1, NUFIP2.
- chr17:40,287,879–40,304,657, 1 gene, copy number 9: CDC6.
- chr20:16,177,933–64,327,972, 1,106 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
